Somatic mutation profile of tumor specimen TCGA-KK-A7AV-01A (aliquot TCGA-KK-A7AV-01A-11D-A32B-08) from TCGA case TCGA-KK-A7AV, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 58.0 years (21,192 days).
Specimen TCGA-KK-A7AV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e502e224-688a-4f48-8743-62eabd8b1c63.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A7AV-11A (Solid Tissue Normal), aliquot TCGA-KK-A7AV-11A-11D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5460721-15f3-438a-bc21-aada0e062342

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, Intron 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRA3 | c.1843C>G p.P615A | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99293418; called by muse, mutect2, varscan2
- LYST | c.364T>A p.L122I | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.02); catalogued as COSV101089789; called by muse, mutect2, varscan2
- MUC16 | c.25639G>C p.V8547L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.07); catalogued as COSV101200306; called by mutect2, varscan2
- PAQR9 | c.866T>G p.F289C | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100503847; called by muse, mutect2, varscan2
- PCDHB1 | c.1237G>T p.E413* | Nonsense Mutation (SNP) | VAF 32/145 reads (22%) | catalogued as rs782652235, COSV100128240; called by muse, mutect2, varscan2
- PLXNB1 | c.1549G>T p.G517C | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV99603024; called by muse, mutect2, varscan2
- RAB38 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.05); catalogued as COSV99703218; called by muse, mutect2, varscan2
- SIM2 | c.709A>G p.S237G | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV99293357; called by muse, mutect2
- SND1 | c.823G>T p.G275C | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100690629; called by muse, mutect2, varscan2
- ARC | c.951C>T p.D317= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV100751732; called by muse, mutect2, varscan2
- NBPF9 | c.1671C>G p.P557= | Silent (SNP) | VAF 16/132 reads (12%) | catalogued as COSV99914191; called by mutect2, varscan2
- PLXNB3 | c.1194C>T p.S398= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as rs782447682, COSV62796486; called by muse, mutect2
- DHX30 | c.3191+22T>A | Intron (SNP) | VAF 3/42 reads (7%) | catalogued as COSV99275673; called by muse, mutect2
- SSX5 | c.70-157C>T | Intron (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100308804; called by muse, mutect2, varscan2
